Somatic mutation profile of tumor specimen TCGA-HM-A3JK-01A (aliquot TCGA-HM-A3JK-01A-11D-A21Q-09) from TCGA case TCGA-HM-A3JK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3; Age at diagnosis: 64.7 years (23,618 days).
Specimen TCGA-HM-A3JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d2407ed-dcac-4a3b-978e-f6c21c934604.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HM-A3JK-10A (Blood Derived Normal), aliquot TCGA-HM-A3JK-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2ec8137-af66-48cb-acd7-d8ff57422018

The open-access MAF lists 64 somatic variants for this specimen: 45 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 40, Silent 19, Nonsense Mutation 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 24/42 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs281875199, CM122566, CM1310758, COSV61809210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.680T>G p.I227S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV61222550; called by muse, mutect2, varscan2
- ACTN3 | c.2082C>G p.N694K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.219); catalogued as COSV100074171; called by muse, mutect2, varscan2
- ADAD1 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56642787, COSV56648017; called by muse, mutect2, varscan2
- AVPR2 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.041); catalogued as rs782160409, COSV61685929; called by muse, mutect2, varscan2
- B4GALNT4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57324095; called by muse, mutect2, varscan2
- BBS2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.476); catalogued as rs150572808; called by muse, mutect2, varscan2
- CACNA1E | c.3737A>G p.N1246S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.137); catalogued as COSV100701537; called by muse, mutect2, varscan2
- CAMLG | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs143564828; called by muse, mutect2, varscan2
- CD1A | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1314744243, COSV99078800, COSV99192250; called by muse, mutect2, varscan2
- CLEC10A | c.733G>A p.E245K (on ENST00000254868 / NM_182906.4; = p.E221K on NM_006344.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV99644616; called by muse, mutect2
- COL15A1 | c.2863G>A p.A955T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs761495633, COSV66646500; called by muse, mutect2, varscan2
- DCHS1 | c.2947C>T p.R983* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55038039; called by muse, mutect2, varscan2
- DENND4B | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs953806868, COSV63410152; called by muse, mutect2, varscan2
- DYNC2H1 | c.9208A>G p.N3070D | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV62097956; called by muse, mutect2, varscan2
- EFHB | c.1391C>G p.S464C | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55549704; called by muse, mutect2, varscan2
- GLRX2 | c.166C>T p.P56S (on ENST00000367439 / NM_197962.3; = p.P57S on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV66472070; called by muse, mutect2
- GPI | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.149); catalogued as COSV62894307; called by muse, mutect2, varscan2
- HUWE1 | c.4540A>G p.I1514V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV53351907; called by muse, mutect2, varscan2
- KIAA1109 | c.4733C>T p.S1578L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV52687093, COSV99148907; called by muse, mutect2, varscan2
- LRCH2 | c.1600C>A p.Q534K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV57753497, COSV57756849; called by muse, mutect2, varscan2
- LRP5 | c.3050G>A p.S1017N | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs957441400, COSV53718227; called by muse, mutect2, varscan2
- LRRN2 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778876933, COSV100912789, COSV99057093; called by muse, mutect2, varscan2
- MAGEB6B | c.158G>A p.R53H | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs371284030, COSV69689855; called by muse, mutect2, varscan2
- MAGEE1 | c.2717G>A p.R906H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.963); catalogued as rs1556839967, COSV63910739; called by muse, mutect2, varscan2
- MPDZ | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs754382614, COSV59919710; called by muse, mutect2, varscan2
- MRPL22 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as rs1258653015, COSV54558804; called by muse, mutect2, varscan2
- OR5P2 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV61490831; called by muse, mutect2, varscan2
- OR8U1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as rs753158239, COSV56416802; called by muse, mutect2, varscan2
- PCDH11X | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as rs1382622123, COSV53478442; called by muse, mutect2, varscan2
- PCDHB11 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV61312483, COSV61314545; called by muse, mutect2, varscan2
- PIK3C2A | c.4225C>T p.L1409F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV56404312; called by muse, mutect2, varscan2
- PLXNA2 | c.3218G>A p.R1073K | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.124); catalogued as COSV65442003; called by muse, mutect2, varscan2
- PTPRG | c.2808G>A p.W936* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | catalogued as COSV55647856; called by muse, mutect2, varscan2
- PTPRK | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs369678964; called by muse, mutect2, varscan2
- SLC12A3 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs144493396, COSV52639158; called by muse, mutect2, varscan2
- STAT2 | c.2309T>C p.V770A | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV57336148; called by muse, mutect2, varscan2
- TNK2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs756000040, COSV57371731; called by muse, mutect2, varscan2
- USP40 | c.2282C>G p.S761C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV52483212; called by muse, mutect2, varscan2
- UTP14A | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV64087249; called by muse, mutect2
- ZC3H3 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs769828841, COSV52791418; called by muse, mutect2, varscan2
- ZNF250 | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs763911257, COSV52969725; called by muse, mutect2, varscan2
- KRT15 | c.1274-2_1279del p.X425_splice | Splice Site (DEL) | VAF 6/23 reads (26%) | called by mutect2, varscan2
- NOTCH1 | c.3063_3075dup p.D1026Cfs*3 | Nonsense Mutation (INS) | VAF 16/58 reads (28%) | called by mutect2, varscan2
- ABHD16B | c.1260C>T p.P420= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1430300019, COSV53863096; called by muse, mutect2, varscan2
- ABI1 | c.192A>G p.Q64= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs954792030, COSV61018083; called by muse, mutect2
- C7 | c.888C>T p.I296= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs757442071, COSV57470913; called by muse, mutect2, varscan2
- CACHD1 | c.909C>T p.S303= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs761699943, COSV51555692; called by muse, mutect2, varscan2
- CFAP65 | c.561C>T p.F187= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV55390778; called by muse, mutect2, varscan2
- CREBBP | c.1866G>A p.K622= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99269114; called by muse, mutect2, varscan2
- GOLGA6A | c.1710C>T p.T570= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1275967298, COSV51805798; called by mutect2, varscan2
- IMPG1 | c.1272A>G p.G424= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV64059176; called by muse, mutect2
- LRP2 | c.8952G>A p.E2984= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55543356, COSV55559747; called by muse, mutect2, varscan2
- LTK | c.1608C>T p.S536= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV53029085; called by muse, mutect2
- MPP5 | c.1020G>A p.P340= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV55530675; called by muse, mutect2, varscan2
- NLRP6 | c.2274G>A p.L758= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs910065133, COSV56460518; called by muse, mutect2, varscan2
- NUP210L | c.4206G>A p.L1402= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV55150771; called by muse, mutect2, varscan2
- OSBPL3 | c.1599G>A p.R533= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV57658347; called by muse, mutect2, varscan2
- PLA2R1 | c.330C>T p.L110= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs147284017, COSV51778970; called by muse, mutect2, varscan2
- PTGER4 | c.27C>T p.S9= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1158882536, COSV56721413; called by muse, mutect2, varscan2
- STK26 | c.1239C>T p.D413= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs757926287, COSV53744677; called by muse, mutect2, varscan2
- TNNC2 | c.180C>T p.I60= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs944382816, COSV65332705, COSV65332940; called by muse, mutect2, varscan2
- UCKL1 | c.747C>T p.I249= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as rs760410784, COSV62403165; called by muse, mutect2, varscan2
